Somatic mutation profile of tumor specimen TCGA-MH-A855-01A (aliquot TCGA-MH-A855-01A-11D-A34Z-10) from TCGA case TCGA-MH-A855, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 52.1 years (19,029 days).
Specimen TCGA-MH-A855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86bb49af-565b-4705-b686-e7fc46bff88d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A855-10A (Blood Derived Normal), aliquot TCGA-MH-A855-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33390807-6087-4cac-b9b6-a6b6a9523ef6

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 26, Silent 7, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.2071G>C p.D691H | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV52223317; called by muse, mutect2
- CACNB4 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV99139849; called by muse, mutect2, varscan2
- CEACAM18 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs200987432; called by muse, mutect2, varscan2
- CHRD | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV99200916; called by muse, mutect2, varscan2
- DHDDS | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99360709; called by muse, mutect2, varscan2
- DPY19L1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758994897, COSV60581770; called by muse, mutect2
- EFCAB6 | c.1812G>C p.E604D | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99414652; called by muse, mutect2, varscan2
- FOXD4L4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1186269882; called by mutect2, varscan2
- GON4L | c.1095A>T p.E365D | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV99676078; called by muse, mutect2, varscan2
- HELZ2 | c.3418G>A p.E1140K (on ENST00000467148 / NM_001037335.2; = p.E571K on NM_033405.3) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100915735; called by muse, mutect2, varscan2
- KDM3A | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as COSV100461108; called by muse, mutect2, varscan2
- KIF1B | c.5377G>C p.A1793P (on ENST00000377086 / NM_001365952.1; = p.A1747P on NM_015074.3) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99824373; called by muse, varscan2
- NPAS2 | c.724T>C p.C242R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100177146, COSV59560483; called by muse, mutect2
- PGBD1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99461056; called by muse, mutect2, varscan2
- PLCB3 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV99657816; called by muse, mutect2, varscan2
- RND2 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99870108; called by muse, mutect2
- SEC23B | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs372083109; called by muse, mutect2, varscan2
- SEPTIN6 | c.100A>G p.N34D | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV100595873; called by muse, mutect2, varscan2
- SH3TC1 | c.1937A>G p.E646G | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV99795402; called by muse, mutect2
- TECRL | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101169482; called by muse, mutect2
- TRIP13 | c.1093A>T p.N365Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99386587; called by muse, mutect2, varscan2
- ZMYND8 | c.1628T>G p.V543G (on ENST00000311275 / NM_001363741.2; = p.V563G on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV99521478; called by muse, mutect2, varscan2
- ZNF584 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100183461; called by muse, mutect2, varscan2
- ZNF721 | c.1948A>T p.I650F (on ENST00000338977; = p.I662F on NM_133474.4) | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100167961; called by muse, mutect2, varscan2
- BOP1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNGB1 | c.1565_1567del p.A522del | In Frame Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- CNTLN | c.1146dup p.L383Tfs*4 | Frame Shift Ins (INS) | VAF 54/198 reads (27%) | called by mutect2, varscan2
- MMP28 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ATF5 | c.534G>T p.P178= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100352430; called by muse, mutect2, varscan2
- CCDC39 | c.216T>C p.L72= | Silent (SNP) | VAF 56/261 reads (21%) | catalogued as COSV99870899; called by muse, mutect2, varscan2
- HOXA2 | c.1056A>T p.V352= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs774959924, COSV99761504; called by muse, mutect2, varscan2
- OR52J3 | c.222C>G p.A74= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV100984959; called by muse, mutect2, varscan2
- SLC4A5 | c.2511G>A p.L837= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- TNFSF10 | c.168T>C p.C56= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV99577975; called by muse, mutect2, varscan2
- ZPLD1 | c.324G>A p.L108= (on ENST00000466937 / NM_001329788.1; = p.L124= on NM_175056.2) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100083633; called by muse, varscan2
